TARGET case TARGET-40-0A4I8S — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/58c43337-cf6f-5b3d-b8d8-d0e25a202200

Demographics
Sex at birth: male; Age at index: 15 years; Vital status: Dead; Days to death: 788 days (2.2 years).

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Classification of tumor: primary; Age at diagnosis: 15.4 years (5,610 days); Year of diagnosis: 2007; Metastasis at diagnosis: No Metastasis; Days to last follow up: 788 days (2.2 years).
   Pathology details: Necrosis percent: 60.
   Treatment given: Protocol identifier: IHRT.
   Treatment given: Therapeutic agents: Doxorubicin.
   Treatment given: Therapeutic agents: Etoposide.
   Treatment given: Therapeutic agents: Ifosfamide.
   Treatment given: Therapeutic agents: Methotrexate.
   Treatment given: Therapeutic agents: Platinum.

Follow-up (2 entries)
- Days to follow up: 315 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 315 days; Days to first event: 315 days; First event: Relapse.
- Days to follow up: 788 days (2.2 years); Year of follow up: 2009.

Biospecimens (2 samples)
- Sample TARGET-40-0A4I8S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-0A4I8S-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 788
- Disease at diagnosis: Non-metastatic (confirmed)
- Primary tumor site: Leg/foot
- Specific tumor site: Femur
- Specific tumor region: Distal
- Definitive Surgery: Limb sparing
- Primary site progression: No
- Site of initial relapse: Lung + other bone
- Histologic response: Stage 1/2 (0-90 % necrosis)
- Relapse Type: Systemic, Locally reurrent
- Therapy: Pre-op Adria/Ifos/MTX + Post-op VP-16/Ifos & Adria/Plat
